Surgical pathology report (de-identified scan), TCGA case TCGA-WX-AA46, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Yale University, specimen TCGA-WX-AA46-01A (Primary Tumor).

[page 1 of 3]
DEPARTMENT OF
PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient:

MR #:

DOB/Age/Sex:

Submitting Physician:

Accession #:

Clinical History and Impression:

year old male with right lobe liver mass
hepatocellular carcinoma on CT scan/MRI
Biopsy - positive for cancer

ICD-O-3
Carcinoma, hepatocellular NOS 8170.3
Site: Liver C22.0
yo 5/30/14

Specimen(s) Received:

1. RIGHT POSTERIOR HEPATECTOMY
2. GALLBLADDER

FINAL DIAGNOSIS

1- LIVER, RIGHT POSTERIOR HEPATECTOMY:

- WELL DIFFERENTIATED HEPATOCELLULAR CARCINOMA (3CM IN MAXIMUM DIMENSION)
- BLOOD CLOT AND NECROTIC TUMOR IDENTIFIED SUGGESTIVE OF VASCULAR INVASION, SEE NOTE
- SURGICAL MARGINS NEGATIVE FOR CARCINOMA
- REMAINING LIVER PARENCHYMA WITHOUT SIGNIFICANT ABNORMALITY
- HISTOPATHOLOGIC STAGE AND GRADE (AJCC 2010): pT2 NX MX, G-1, Stage II

2. GALLBLADDER, CHOLECYSTECTOMY:

- CHOLELITHIASIS
- CHRONIC CHOLECYSTITIS

NOTE: The entire tumor has been submitted for histology and shows well differentiated histology, and in many areas has an adenoma like appearance. Focal areas show bile ductular reaction in the lesion as highlighted by CK7 and 19 stains. There is focal telangiectasia also present. The CK7 also shows positivity in many periseptal hepatocytes. Stain for glypican-3 is negative, while Beta-catenin, HSP70 and Amyloid A are negative. Glutamine synthetase shows a patchy map-like positivity. CD34 shows extensive staining in the sinusoidal endothelial cells. The reticulin stain reveals that the hepatic cords are thickened focally and there is mild cytologic atypia. Overall, the features are of a well differentiated hepatocellular carcinoma, and whether it arose in a background of adenoma

[page 2 of 3]
remains a speculation.

Immediately next to the tumor nodule grossly there is a large portal tract with a necrotic appearing tumor thrombus in a portal vessel. Histologically extensive sampling from this area shows this to be completely necrotic tumor associated with blood clot surrounded by dense scar and extensive hemosiderin laden macrophages. Although a definite venous wall is difficult to identify around the necrotic tumor, this is interpreted as vascular invasion by the tumor. Few thrombosed vessels are identified around this area as highlighted with EVG stains. The case has been seen with Dr. _____ who concurs.

SYNOPTIC SUMMARY

PROCEDURE: Partial hepatectomy

SPECIMEN TYPE: Liver, gallbladder

TUMOR SIZE: Greatest Dimension: 3 cm

TUMOR FOCALITY: Solitary

HISTOLOGIC TYPE: Hepatocellular carcinoma

HISTOLOGIC GRADE: G1: Well differentiated

TUMOR EXTENSION: Tumor confined to liver

MARGINS:

Parenchymal Margin: Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 10 mm

LYMPH-VASCULAR INVASION

Macroscopic Venous (Large Vessel) Invasion (V): Present

Microscopic (Small Vessel) Invasion (L): Not identified

PATHOLOGIC STAGE (TNM):

Primary Tumor (pT): pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm.

Regional Lymph Nodes (pN): pNx: Cannot be assessed.

PATHOLOGIC STAGE (AJCC 6th ed): pT2 pN0 pM0, Stage II

ADDITIONAL PATHOLOGIC FINDINGS: None identified

CLINICAL HISTORY: Not known

Pathologist:

** Report Electronically Signed Out **

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

[page 3 of 3]
Gross Specimen

Gross Specimen

Gross Description:

1. Received fresh, labeled with the patient's name and "right posterior hepatectomy" is a segment of liver weighing 397 grams and measuring 14 x 12 x 6.5 cm. The capsular surface appears shiny and smooth. The surgical margin is identified and inked black. The specimen is serially sectioned at 1 cm intervals and reveals a 3 x 2.5 x 2 cm tan-white, well-circumscribed subcapsular mass, partially with central hemorrhage and necrosis. A 1.5 x 1.5 cm adjacent area filled with necrotic material is present which appears to be tumor thrombus in a portal vessel which is about 0.4 cm from the surgical margin. A 0.5 cm tan-brown nodule is present 0.8 cm from the mass. No other mass is grossly identified. The remaining liver looks unremarkable without any evidence of cirrhosis. Representative sections are submitted, as follows: cassette 1=tumor with capsule, cassettes 2-3=tumor with central necrosis, cassettes 4-5=representative sections from adjacent area filled with necrotic material, cassettes 6-7=small fibrotic area to margin (between tumor and margin), cassettes 8-10=tumor with adjacent area filled with necrotic material and small fibrotic area, as per diagram, cassette 11=tumor to normal liver, cassette 12=representative sections from normal liver. Cassettes 13-15= tumor, cassette 16=tumor with thrombus.

2. Received fresh, labeled with the patient's name and "gallbladder" is a 9 x 3 x 0.8 cm gallbladder. The serosal surface appears shiny and smooth. The liver bed area is identified. A clipped cystic duct is present. The cystic duct margin is inked in black and the gallbladder is opened to reveal multiple yellow stones measuring 0.1-0.2 cm. The mucosa appears granular and the wall thickness measures 0.2-0.6 cm in maximal thickness. No mass lesion or perforation is grossly identified. A representative section to include the cystic duct margin are submitted in one cassette.

Summary of Stains Performed and Reviewed

	Count
Amyloid A *	1
Amyloid A *	1
CD34 *	1
Diastase PAS	1
Elastic-Verhoeff's von Giesen	2
Glutamine Synthetase *	1
Glypican-3 *	2
H&E, Recut, Level	5
HSP-70 *	1
Keratin, CK19 *	2
Keratin, CK7 *	2
Negative Control *	2
Prussian Blue (Iron)	1
Reticulum, Gordon	3
Trichrome, Klatskin	1

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

	# Blocks	Designation	#	Description
Part 1] RIGHT POSTERIOR HEPATECTOMY	16	LIV	(16)	Liver
Part 2] GALLBLADDER	1	GB	(1)	Gallbladder

Total: 17

Source: NCI Genomic Data Commons file 2657f45c-2a3c-445c-bee4-16b6410619f7 (TCGA-WX-AA46.A767B73F-5C51-47E8-A569-E112DBB987FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).